Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91W, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91W-01A (Primary Tumor).

IGD 0-3
Adenocarcinoma, intestinal 8/14/13
Site Body & stomach C16-2
JH 3/18/14

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1-Esophageal margin:

ESOPHAGEAL MUCOSA UNINVOLVED BY NEOPLASIA.

2- Stomach:

MODERATELY DIFFERENTIATED ADENOCARCINOMA, INTESTINAL LAUREN TYPE.

LARGEST SIZE: 9.0 CM, INVASION TO ADJACENT FAT TISSUE.

PRESENCE OF LYMPHATIC INVASION AND OF VENOUS INVASION.

PRESENCE OF PERINEURAL INVASION.

MILD PERITUMOR INFLAMMATORY INFILTRATE.

SURGICAL MARGINS UNINVOLVED BY NEOPLASIA.

ADJACENT MUCOSA WITH MODERATE PANGASTRITIS AND WITH INCOMPLETE INTESTINAL METAPLASIA.

3-Gallbladder:

CHRONIC CHOLECISTITIS.

CHOLESTEROSIS.

4-Distal margin:

ESOPHAGEAL MUCOSA UNINVOLVED BY NEOPLASIA.

5- Omentum:

UNINVOLVED BY NEOPLASIA.

6- Lymphadenectomy according standardization:

METASTATIC ADENOCARCINOMA IN 5 OF 25 LYMPH NODES, DISTRIBUTED AS FOLLOWS:

5/12 LESSER CURVATURE LYMPH NODES,

0/3 RIGHT GASTROEPIPLOIC LYMPH NODES (4d),

0/6 INFRAPYLORIC LYMPH NODES,

0/2 COMMON HEPATIC ARTERY LYMPH NODES,

0/1 CELIAC TRUNK LYMPH NODE,

AND 0/1 SPLENIC ARTERY LYMPH NODE.

RIGHT PARACARDIC, LEFT PARACARDIC, SHORT GASTRIC ARTERY (4sa),

LEFT GASTROEPIPLOIC AND SUPRAPYLORIC CHAINS: FAT TISSUE

UNINVOLVED BY NEOPLASIA (0/0).

IPAX Discrepancy		
Prior Abdominal History		
Qualification of Primary Tumor		
Case is for cln		
Date Received	11/5/13	

Source: NCI Genomic Data Commons file d80542e6-128b-468e-b522-3e3fe1869cbc (TCGA-VQ-A91W.A617D05B-9954-4C15-A957-23D04A8C1764.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).